Gene-level copy-number profile of tumor specimen ALCH-B1T7-TTP1-A from ALCHEMIST case ALCH-B1T7, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 60.4 years (22,052 days).
Specimen ALCH-B1T7-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 744b289a-ef5a-46a1-999b-0d89a5f85339.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B1T7-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,713 have no estimate.
https://portal.gdc.cancer.gov/files/7b19fdec-58e3-4e3c-ba92-395bec526cf5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 29; copy number 1: 3,265; copy number 2: 55,527; copy number 3: 83; copy number 4: 5; copy number 5: 1.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:2,090,195–2,090,284, 1 gene (within-gene range 0–1): MIR1225.
- chr17:81,976,807–82,031,151, 3 genes: ASPSCR1, CENPX, LRRC45.
- chr20:62,307,955–62,367,312, 3 genes (within-gene range 0–2): LAMA5, MIR4758, LAMA5-AS1.
- chr20:63,540,810–63,556,695, 3 genes: SRMS, AL121829.2, FNDC11.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:42,939,775–42,939,998, 1 gene, copy number 5: AC109810.1.

Autosomal genes at a single copy (total copy number 1): 454. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
